Gene-level copy-number profile of tumor specimen TCGA-37-3783-01A from TCGA case TCGA-37-3783, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 51.3 years (18,728 days).
Specimen TCGA-37-3783-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.74090fd6-5a4d-4e5f-8cc1-19eaf41d7375.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-37-3783-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7580a73d-3c19-4085-9a99-901b9db2d2d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 11,159; copy number 2: 35,293; copy number 3: 7,488; copy number 4: 4,259; copy number 5: 1,251; copy number 6: 183; copy number 7: 133; copy number 8: 8; copy number 10: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-37-3783-01A-01D-1195-01): tumor purity 0.36, ploidy 2.27, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–24,088,051, 25 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1.
- chr13:49,956,670–50,125,720, 12 genes: DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5.
- chr13:50,082,295–50,173,181, 5 genes: AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,576 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:177,170,958–182,616,629, 108 genes, copy number 5 (broad region; genes not listed).
- chr1:184,385,753–194,488,205, 119 genes, copy number 5 (broad region; genes not listed).
- chr1:214,603,195–232,223,145, 369 genes, copy number 5–6 (broad region; genes not listed).
- chr1:234,709,383–240,612,155, 108 genes, copy number 6 (broad region; genes not listed).
- chr3:143,265,222–143,848,485, 1 gene, copy number 5 (within-gene range 4–5): SLC9A9.
- chr3:143,620,528–146,606,216, 23 genes, copy number 5: AC073358.1, AC107421.1, DIPK2A, RNA5SP144, AC011592.1, LARP7P4, GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2, AC069528.2, PLSCR1, RNU6-428P, PLSCR5, PLSCR5-AS1.
- chr3:164,001,606–167,407,874, 26 genes, copy number 5 (within-gene range 4–5): AC084017.1, MIR1263, LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX.
- chr3:190,305,707–192,917,856, 29 genes, copy number 5: CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC, OSTN, OSTN-AS1, UTS2B, CCDC50, AC073365.1, PYDC2, Y_RNA, AC026320.2, AC026320.1, AC026320.3, RN7SKP222, FGF12, FGF12-AS1, FGF12-AS2, FGF12-AS3, AC026671.1, RNU1-20P, MB21D2.
- chr6:127,968,785–132,714,055, 67 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:79,543,911–89,754,726, 87 genes, copy number 5 (broad region; genes not listed).
- chr7:90,403,434–109,999,624, 444 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:110,215,891–110,216,380, 1 gene, copy number 5: AC073114.2.
- chr11:31,784,779–33,033,582, 28 genes, copy number 5 (within-gene range 1–5): PAX6, PAUPAR, AL035078.4, AL035078.1, AL035078.3, AL035078.2, U3, EIF4A2P5, RCN1, AL078612.1, THEM7P, AL078612.2, WT1, WT1-AS, AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4, EIF3M, HNRNPA3P9, CCDC73, AL049714.1, PRRG4, QSER1, Y_RNA, DEPDC7.
- chr14:49,057,713–49,077,505, 1 gene, copy number 10: AL110505.1.
- chr14:49,893,082–50,105,043, 8 genes, copy number 8 (within-gene range 2–8): ARF6, RNU6-189P, Metazoa_SRP, LINC01588, MIR6076, PDLIM1P1, AL117692.1, RN7SKP193.
- chr17:73,163,035–76,586,956, 157 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,765. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
